FM case AD699 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/929f9371-da19-4cf4-9b5d-36c8d2370cad

Male, 63.4 years: Adenoid cystic carcinoma (ICD-O-3 8200/3) of the head, face or neck; specimen biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
